Somatic mutation profile of tumor specimen TCGA-14-1456-01B (aliquot TCGA-14-1456-01B-01D-1494-08) from TCGA case TCGA-14-1456, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 23.8 years (8,710 days).
Specimen TCGA-14-1456-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ff1e555-31f5-48ac-afc6-a4f7bdb5ea56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1456-10A (Blood Derived Normal), aliquot TCGA-14-1456-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/029fde2a-49ec-4047-9289-1a699b687b08

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 21, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 32/139 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 41/150 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1135A>G p.K379E (on ENST00000521381 / NM_181523.3; = p.K109E on NM_181504.4) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57124239; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 42/57 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARSK | c.1276T>C p.Y426H | Missense Mutation (SNP) | VAF 115/275 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66169257; called by muse, mutect2, varscan2
- ATRX | c.5529G>C p.Q1843H | Missense Mutation (SNP) | VAF 62/83 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64871854; called by muse, mutect2, varscan2
- C16orf54 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs199652256, COSV61476594; called by muse, varscan2
- CATSPER4 | c.670T>G p.F224V | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV58792324; called by muse, mutect2
- CD2AP | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63759325; called by muse, mutect2, varscan2
- CHD6 | c.5495G>A p.C1832Y | Missense Mutation (SNP) | VAF 153/446 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64688483, COSV64694498; called by muse, mutect2, varscan2
- GABBR2 | c.2812G>C p.V938L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.956); catalogued as COSV52293902; called by muse, mutect2, varscan2
- KCTD2 | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as COSV56902385; called by muse, mutect2, varscan2
- MSH5 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65172415; called by muse, mutect2
- OGDHL | c.777G>T p.W259C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65100875; called by muse, mutect2
- PER2 | c.3562C>T p.R1188C | Missense Mutation (SNP) | VAF 175/414 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs748810685, COSV54521568; called by muse, mutect2, varscan2
- PKD1L2 | c.2389G>A p.A797T | Missense Mutation (SNP) | VAF 21/235 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs370023428; called by muse, mutect2
- PREX1 | c.2632G>A p.G878S | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs779765138, COSV64248032, COSV64251237; called by muse, mutect2, varscan2
- SDCCAG8 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs576988620, COSV59405000; called by muse, varscan2
- SLC27A2 | c.1064A>G p.D355G | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as COSV51057514; called by muse, mutect2, varscan2
- SPP2 | c.234C>G p.N78K | Missense Mutation (SNP) | VAF 72/204 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV51444482; called by muse, mutect2, varscan2
- SULF1 | c.203A>C p.K68T | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as rs767772359, COSV52673873; called by muse, mutect2, varscan2
- EGFR | c.594C>T p.S198= | Silent (SNP) | VAF 63/268 reads (24%) | catalogued as rs370376501, COSV51841162; called by muse, mutect2, varscan2
- SEC11A | c.111G>A p.K37= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as COSV51612109; called by muse, mutect2, varscan2
- TBX22 | c.726C>A p.P242= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV64785035; called by muse, mutect2
- ZNF251 | c.1230C>T p.C410= | Silent (SNP) | VAF 28/440 reads (6%) | catalogued as rs369726950; called by muse, mutect2
